Somatic mutation profile of tumor specimen TCGA-XU-A930-01A (aliquot TCGA-XU-A930-01A-11D-A423-09) from TCGA case TCGA-XU-A930, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.2 years (15,777 days).
Specimen TCGA-XU-A930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 329b7a25-6460-4938-b109-2e812daa4601.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A930-10A (Blood Derived Normal), aliquot TCGA-XU-A930-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bcbbc47-0148-4287-97ea-25e011130374

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 3, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMP5 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as rs550837639, COSV63700675; called by muse, mutect2, varscan2
- COL5A2 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386081744, COSV66408575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNM3 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs371617456, COSV62464646; called by muse, mutect2, varscan2
- EED | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54556403; called by muse, mutect2, varscan2
- NAA16 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65064990; called by muse, mutect2, varscan2
- PHLDA1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99876676; called by muse, mutect2, varscan2
- PPP1R12B | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs143792888; called by muse, mutect2, varscan2
- UBQLN2 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV57738897; called by muse, mutect2
- APCDD1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DIP2C | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- GABARAP | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GAS2L2 | c.2525G>A p.G842E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO15A | c.5094G>T p.E1698D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPFIA2 | c.687A>C p.K229N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PSMC2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- SRPX2 | c.1252A>C p.M418L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZAN | c.8377C>T p.Q2793* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.2574C>T p.L858= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99720886; called by muse, mutect2, varscan2
- RUFY1 | c.678G>C p.V226= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- SLC9A2 | c.2394G>A p.S798= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1216068801, COSV52129301; called by muse, mutect2
- TGM5 | c.2019C>A p.V673= (on ENST00000220420 / NM_201631.4; = p.V591= on NM_004245.4) | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- MIR205 | n.96_97dup | RNA (INS) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
